Gene-level copy-number profile of tumor specimen TCGA-CV-5431-01A from TCGA case TCGA-CV-5431, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 73.8 years (26,953 days).
Specimen TCGA-CV-5431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.aee7c259-f93a-47b5-9358-1db36a81b06e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5431-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc170515-25e4-40b0-94ba-d54f95b7638b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 478; copy number 1: 2,867; copy number 2: 12,664; copy number 3: 22,217; copy number 4: 10,492; copy number 5: 3,143; copy number 6: 4,293; copy number 7: 1,854; copy number 8: 457; copy number 9: 542; copy number 10: 851; copy number 11: 142; copy number 12: 29; copy number 13: 23; copy number 16: 63; copy number 17: 12; copy number 18: 43; copy number 19: 11; copy number 25: 11; copy number 47: 28; copy number 49: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CV-5431-01): tumor purity 0.35, ploidy 3.31, whole-genome doublings 1 (call status: legacy_maf_call).

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr9:21,135,598–22,214,672, 51 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,069 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,994,531–152,196,699, 10 genes, copy number 7 (within-gene range 6–7): AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:219,685,427–220,784,815, 29 genes, copy number 7 (within-gene range 6–7): SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2.
- chr3:151,425,384–198,222,513, 817 genes, copy number 7 (broad region; genes not listed).
- chr4:76,708,853–77,819,615, 19 genes, copy number 7 (within-gene range 2–7): SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L.
- chr7:11,820,317–57,837,046, 848 genes, copy number 7–11 (broad region; genes not listed).
- chr7:86,216,785–124,929,983, 677 genes, copy number 10–19 (broad region; genes not listed).
- chr7:125,033,453–125,035,301, 1 gene, copy number 19: EEF1GP1.
- chr11:69,147,228–70,436,584, 38 genes, copy number 12–16: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 16: AP001271.1.
- chr12:66,767–34,249,958, 850 genes, copy number 8–13 (within-gene range 4–13) (broad region; genes not listed).
- chr13:57,140,918–75,807,120, 161 genes, copy number 8–18 (within-gene range 4–18) (broad region; genes not listed).
- chr13:75,631,271–75,689,197, 2 genes, copy number 11: AL137244.1, FAM204CP.
- chr13:112,602,828–114,337,626, 59 genes, copy number 9: AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr16:10,760,919–16,664,135, 169 genes, copy number 7–25 (within-gene range 2–25) (broad region; genes not listed).
- chr17:35,188,522–35,578,863, 34 genes, copy number 16: AC022916.2, AC022916.3, SLC35G3, AC022916.1, SLFN5, AC022706.1, AC060766.2, SLFN11, AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12.
- chr17:35,596,904–35,597,128, 1 gene, copy number 16: AC004134.1.
- chr17:36,634,069–37,056,871, 12 genes, copy number 17: AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:39,063,313–39,154,394, 1 gene, copy number 47 (within-gene range 4–47): PLXDC1.
- chr17:39,156,894–39,864,312, 27 genes, copy number 47: ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr17:70,312,831–70,779,230, 3 genes, copy number 49: AC011990.1, AC005771.1, AC007423.1.
- chr19:44,613,563–49,256,102, 264 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr22:28,992,721–30,177,075, 46 genes, copy number 8 (within-gene range 3–8): ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1, EWSR1, GAS2L1, RASL10A, AC002059.1, AP1B1, AC002059.2, SNORD125, AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51.

Autosomal genes at a single copy (total copy number 1): 386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
